Gene-level copy-number profile of tumor specimen TCGA-BB-7871-01A from TCGA case TCGA-BB-7871, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.1 years (23,409 days).
Specimen TCGA-BB-7871-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.158eccc7-df29-4f24-9673-30124be9b776.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BB-7871-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/15c9e52d-2823-4171-87e7-bf3052b15c6e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,929; copy number 2: 36,911; copy number 3: 5,036; copy number 4: 920; copy number 5: 270; copy number 6: 413; copy number 7: 135; copy number 8: 136; copy number 14: 24; copy number 24: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-BB-7871-01): tumor purity 0.59, ploidy 1.88, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,016 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,457,835–34,165,842, 43 genes, copy number 5–7 (within-gene range 2–7): RN7SL122P, AL033529.1, ZBTB8B, ZBTB8A, ZBTB8OS, Y_RNA, RBBP4, SYNC, AC114489.1, KIAA1522, YARS1, S100PBP, FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL031602.1, AL355864.1, AL355864.2, AL020995.1, AK2, Metazoa_SRP, AZIN2, AL662907.1, TRIM62, AL662907.2, AL662907.3, ZNF362, AL513327.2, A3GALT2, AL513327.1, PHC2, MIR3605, RN7SKP16, PHC2-AS1, TLR12P, ZSCAN20, AC115285.1, CSMD2, HSPD1P14, HMGB4, CSMD2-AS1.
- chr3:159,839,861–198,222,513, 680 genes, copy number 6–8 (broad region; genes not listed).
- chr8:31,639,222–32,855,666, 1 gene, copy number 5 (within-gene range 1–5): NRG1.
- chr8:32,026,210–43,674,591, 230 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr11:68,754,620–71,252,577, 62 genes, copy number 14–24 (within-gene range 2–24) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,835. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
